Surgical pathology report (de-identified scan), TCGA case TCGA-42-2593, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2593-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Right tube and ovary
- B. Left ovary
- C. Small bowel
- D. Omentum
- E. Uterus and cervix
- F. Omentum

CLINICAL NOTES

FROZEN SECTION DIAGNOSIS

A and B. Ovaries, right and left, resection: Papillary serous carcinoma

GROSS DESCRIPTION

A. The specimen is received unfixed, labeled "right tube and ovary" and consists of a tan-white piece of soft tissue

compatible with cystic ovary measuring 3.8 x 3.2 x 2.7 cm. There is adjacent pink soft tissue measuring 3.5 x 2 x 0.5 cm. The ovary has multiple cysts in it. Some are hemorrhagic. neoplastic. A portion of the ovary is taken diagnosis as requested. Additional sections

B. The specimen is received unfixed, labeled "left ovary,"

and consists of a piece of tan soft tissue measuring 5.5 x 4.5 x 3.5 cm on cut section. The specimen is cystic and contains a tan solid area measuring 3.5 cm in greatest dimension. A portion of

the solid area is taken for possible research purposes. A portion of the specimen is taken for frozen section diagnosis. RS-6.

C. Specimen is received unfixed labeled "small bowel" and consists of a pink to purplish segment of small bowel measuring 11.5 cm in length and 3.2 cm in diameter. There are some white plaque-like lesions on the serosal surface measuring up to

0.3

[page 2 of 3]
GROSS DESCRIPTION

cm in diameter. These lesions are less than 0.1 cm in thickness. The bowel was opened with a single longitudinal incision. The mucosal surface is unremarkable. Sections after fixation. RS-4.

D. Specimen is received in formalin labeled "omentum".

This specimen was previously examined by [REDACTED] [REDACTED] for tissue procurement and consists of six pieces of tan and yellow rubbery firm tissue measuring 10.5 x 5.5 x 1.4 cm in aggregate. RS-3.

E. Specimen is received unfixed labeled "uterus and cervix" and consists of a 144 gm uterus measuring 9 x 6 x 5.5 cm. The serosal surface has a granular appearance. The ectocervix is tan and measures 3 x 2.2 cm. The external os measures

1 x 0.1 cm. The uterus is opened with a single incision in one lateral edge. The uterine cavity contains moderate tan endometrium.

There is an area of endometrium fragments resembling benign polyp near one cornu measuring 1.2 cm in greatest dimension. On cut section, two intramural leiomyoma-like masses are present measuring 3 and 2 cm in diameter. Sections after fixation. RS-9.

F. Specimen is received unfixed labeled "omentum" and consists of two pieces of tan and yellow rubbery firm tissue measuring 6 x 5 x 1.2 cm in aggregate. Sections after fixation. RS-4.

MICROSCOPIC DESCRIPTION

Tumor type: Papillary serous carcinoma. There is focal micropapillary grown pattern (block B6)

Tumor grade: FIGO grade 3 (out of 3)

Tumor size: Carcinoma is 5.5 cm in the left ovary

Mitotic rate: 38 mitoses/10 HPFs (1 HPF = 0.19 sq mm)

Extracapsular tumor: Present

[page 3 of 3]
MICROSCOPIC DESCRIPTION

pTNM stage: T3c

Carcinoma is present in the right ovary and hilar soft tissue, on the serosal surface of the small bowel, in the omentum, and in mural lymphatics in the outer part of the uterine wall. Carcinoma is present in blood vessels and lymphatics in sections from the omentum.

4x4, 3x2, 14x2

DIAGNOSIS

- A. Ovary and uterine tube, right, resection:
Poorly differentiated papillary serous carcinoma.
- B. Ovary, left, resection:
Poorly differentiated papillary serous carcinoma.
- C. Small bowel, segmental resection:
Metastatic serous carcinoma to the serosal surface.
- D, F. Omentum, resection:
Metastatic poorly differentiated serous carcinoma.
- E. Uterus, resection:
Cervix: No pathological diagnosis.
Endometrium: Inactive type endometrium. Benign endometrial polyp.
Myometrium: Leiomyoma. Carcinoma in outer mural lymphatics.
Parametrium: Metastatic papillary serous carcinoma.
-

Source: NCI Genomic Data Commons file 73825e25-4f6d-4d30-abd6-4edff5c558c8 (TCGA-42-2593.302C2898-9B19-494B-86A5-F0FF3CAB7163.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).